Gene-level copy-number profile of tumor specimen CUPP-B38I-TTM1-A from CCG case CUPP-B38I, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: female; Vital status: Alive; Primary diagnosis: Metastatic signet ring cell carcinoma; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage III; Age at diagnosis: 56.6 years (20,689 days).
Specimen CUPP-B38I-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 15f07f34-5d61-47a7-9217-7a9c6c1dbac9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B38I-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,271 have no estimate.
https://portal.gdc.cancer.gov/files/8ba5ecf0-9e42-4f1c-92b5-a15eb1b14ec9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 308; copy number 1: 7,589; copy number 2: 32,938; copy number 3: 13,126; copy number 4: 3,694; copy number 5: 463; copy number 6: 164; copy number 7: 37; copy number 8: 4; copy number 9: 4; copy number 10: 23; copy number 12: 2.

Homozygous deletions (total copy number 0; autosomes only): 308 genes in 89 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,069,168–3,487,627, 9 genes: PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1, ARHGEF16, AL512413.1.
- chr1:4,412,027–4,792,534, 5 genes: LINC01777, Z98747.1, LINC01646, AJAP1, Z98886.1.
- chr1:5,478,736–5,668,295, 4 genes: Z98259.3, Z98259.1, AL365255.1, Z97988.1.
- chr1:30,013,952–30,226,615, 3 genes: LINC01648, AL137076.1, AL021921.1.
- chr1:33,513,999–34,277,292, 7 genes (within-gene range 0–1): CSMD2, HSPD1P14, HMGB4, CSMD2-AS1, RNA5SP42, C1orf94, AC115286.1.
- chr1:110,473,756–110,519,175, 4 genes: AL358215.3, CYMP, CYMP-AS1, KCNA10.
- chr2:89,319,625–89,600,680, 3 genes: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr4:3,758,748–3,910,604, 5 genes: LINC02600, ADRA2C, OR7E163P, OR7E162P, AC147876.1.
- chr4:10,143,367–10,295,579, 10 genes: AC093664.1, AC006499.6, AC006499.1, AC006499.8, RAF1P1, AC006499.4, AC006499.2, AC006499.3, AC006499.5, AC006499.7.
- chr4:77,157,207–77,433,388, 4 genes (within-gene range 0–2): CCNG2, AC008638.3, AC008638.2, AC008638.1.
- chr5:135,450,613–135,918,161, 12 genes (within-gene range 0–2): AC022092.1, NEUROG1, AC034206.1, CXCL14, SLC25A48, SLC25A48-AS1, AC011431.1, MIR5692C1, AC114296.1, IL9, AC002428.2, AC002428.1.
- chr5:170,028,488–170,199,141, 4 genes (within-gene range 0–2): MIR378E, FOXI1, KRT18P41, LINC01187.
- chr6:167,325,071–167,768,568, 7 genes: TTLL2, AL021331.1, TCP10L3, LINC02538, AL356123.2, LINC02487, AL009178.1.
- chr6:168,292,830–168,375,355, 3 genes (within-gene range 0–1): DACT2, AL606970.1, AL138918.1.
- chr6:170,160,606–170,279,887, 6 genes: AL596442.1, AL596442.2, RPL12P23, AL109910.1, AL109910.2, LINC01624.
- chr8:139,096,305–139,704,109, 6 genes: AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9.
- chr10:123,356,450–123,537,767, 2 genes: LINC02641, AL160290.1.
- chr10:128,912,810–129,291,722, 3 genes: LINC02667, AL355537.1, AL391869.1.
- chr10:129,835,233–129,973,053, 5 genes (within-gene range 0–1): EBF3, AL354950.2, MIR4297, AL354950.1, AL354950.3.
- chr10:131,772,398–131,795,277, 2 genes: LINC01164, AL450307.1.
- chr12:30,926,428–31,015,806, 3 genes: TSPAN11, AC008013.1, AC008013.2.
- chr12:127,274,265–127,321,529, 3 genes: LINC02376, AC073913.1, RNU1-104P.
- chr12:130,953,907–131,141,469, 11 genes (within-gene range 0–1): ADGRD1, AC073862.3, AC073862.4, AC073862.5, AC073862.1, AC073862.2, AC078925.4, ADGRD1-AS1, AC078925.2, AC078925.3, AC078925.1.
- chr13:111,316,184–112,331,225, 12 genes: TEX29, AL359649.1, LINC02337, LINC00354, AL138691.1, SOX1-OT, SOX1, AL356961.1, LINC00404, LINC01070, LINC01043, LINC01044.
- chr14:93,904,730–93,976,739, 5 genes: FAM181A-AS1, FAM181A, ASB2, AL132642.1, MIR4506.
- chr14:100,779,410–100,861,031, 7 genes (within-gene range 0–1): MEG3, MIR2392, AL117190.5, AL117190.3, AL117190.7, AL117190.2, MIR770.
- chr14:104,450,979–104,605,647, 4 genes (within-gene range 0–1): CEND1P1, TMEM179, C14orf180, BX927359.1.
- chr16:51,107,571–51,151,367, 3 genes: SOD1P2, SALL1, AC009166.1.
- chr16:55,259,969–55,793,960, 17 genes: AC109462.1, RN7SL841P, AC109462.3, IRX6, AC109462.2, RPL31P56, MMP2, AC007336.2, MMP2-AS1, AC007336.3, LPCAT2, AC007336.1, CAPNS2, SLC6A2, AC136621.1, CES1P2, CES1P1.
- chr16:82,626,965–83,800,640, 12 genes (within-gene range 0–1): CDH13, MIR8058, AC099506.2, AC099506.1, AC099506.3, RN7SL134P, AC125793.1, AC009142.1, MIR3182, AC009063.3, AC009063.4, AC009063.2.
- chr16:86,035,627–86,301,303, 7 genes (within-gene range 0–1): AC092723.2, AC135012.1, AC135012.2, AC135012.3, LINC01082, LINC01081, Y_RNA.
- chr16:86,331,632–86,555,235, 8 genes: LINC00917, AC092327.2, AC092327.1, FENDRR, FOXF1, AC009108.3, AC009108.1, MTHFSD.
- chr17:21,442,805–21,521,269, 6 genes: AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5.
- chr17:36,377,531–36,439,566, 3 genes (within-gene range 0–1): TBC1D3H, RNU6-1192P, TBC1D3F.
- chr18:77,970,637–78,484,867, 5 genes: LINC01029, AC134978.1, RNU6-655P, AC107892.1, AC087399.1.
- chr20:43,189,998–43,231,260, 3 genes: AL021395.1, RN7SL666P, PPIAP21.
- chr20:62,513,909–62,570,764, 5 genes: AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2.
- chr21:41,739,369–41,767,089, 3 genes (within-gene range 0–3): RIPK4, AP001615.1, MIR6814.
- chr22:22,704,265–22,739,187, 7 genes (within-gene range 0–1): IGLV3-22, IGLV3-21, IGLVI-20, IGLV3-19, AC244250.3, IGLV2-18, IGLV3-17.
- chr22:48,274,364–49,657,542, 15 genes (within-gene range 0–1): MIR3201, Z82249.1, TAFA5, Z84468.1, MIR4535, LINC01310, RPL35P8, Z82202.1, C22orf34, AL008636.1, AL031593.1, MIR3667, Z97192.1, Z97192.2, Z97192.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 637 genes in 83 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,032,832–10,181,239, 3 genes, copy number 5 (within-gene range 4–5): UBE4B, AL590639.1, PGAM1P11.
- chr1:150,045,660–150,720,895, 32 genes, copy number 5–7: AC244033.2, AC244033.1, VPS45, PLEKHO1, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P.
- chr1:150,926,263–151,459,494, 35 genes, copy number 5–6: SETDB1, CERS2, AL590133.2, AL590133.1, ANXA9, MINDY1, PRUNE1, RNU6-884P, BNIPL, C1orf56, CDC42SE1, MLLT11, GABPB2, RPS29P29, AL592424.1, SEMA6C, TNFAIP8L2, SCNM1, LYSMD1, TMOD4, VPS72, PIP5K1A, PSMD4, ZNF687-AS1, ZNF687, PI4KB, RN7SL444P, AL391069.2, RFX5, AL391069.1, RFX5-AS1, SELENBP1, PSMB4, POGZ, RNY4P25.
- chr1:155,208,699–155,859,400, 32 genes, copy number 5 (within-gene range 4–5): MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1, ASH1L, MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P, POU5F1P4, ASH1L-AS1, AL353807.4, DAP3P1, AL353807.1, AL353807.2, MSTO1, AL353807.3, AL353807.5, YY1AP1, DAP3, AL162734.1, MSTO2P, GON4L.
- chr1:173,714,941–173,858,808, 6 genes, copy number 6–7: KLHL20, BX248409.1, RN7SKP160, CENPL, Y_RNA, DARS2.
- chr1:235,295,865–235,452,443, 8 genes, copy number 6 (within-gene range 3–6): RPL23AP23, GGPS1, AL357556.3, AL391994.1, AL357556.1, AL357556.5, TBCE, RPS21P1.
- chr2:47,345,158–47,387,601, 4 genes, copy number 5: EPCAM, RN7SKP119, MIR559, Metazoa_SRP.
- chr2:61,471,188–61,605,722, 6 genes, copy number 5: AC016727.1, XPO1, AC016727.3, AC016727.2, RPS29P10, RNU6-1145P.
- chr4:39,698,109–39,782,792, 5 genes, copy number 6: UBE2K, Y_RNA, AC108471.1, RN7SL558P, ZBTB12BP.
- chr4:70,688,532–70,704,491, 4 genes, copy number 5 (within-gene range 4–5): UTP3, RNU6-520P, RNU6-784P, AC009570.1.
- chr5:69,631,963–69,920,867, 5 genes, copy number 6–9: AC139495.2, GUSBP3, AC139495.1, GUSBP13, AC131392.1.
- chr7:40,107,288–40,134,622, 4 genes, copy number 5: AC006023.2, AC006023.1, MPLKIP, Y_RNA.
- chr7:73,732,569–74,789,376, 24 genes, copy number 5–8: RN7SL265P, ABHD11-AS1, ABHD11, CLDN3, CLDN4, METTL27, TMEM270, AC099398.1, ELN, ELN-AS1, LIMK1, EIF4H, MIR590, LAT2, RFC2, CLIP2, GTF2IRD1, RNA5SP233, AC211433.2, AC211433.3, GTF2I, AC211433.1, PHBP15, NCF1.
- chr7:74,843,754–75,789,896, 36 genes, copy number 5–6 (within-gene range 2–6): STAG3L2, PMS2P5, Y_RNA, SPDYE12P, CASTOR2, RCC1L, Metazoa_SRP, GTF2IRD2B, NCF1C, GTF2IP1, PHBP6, AC211486.5, AC211486.2, AC211486.4, SPDYE13, PMS2P10, Y_RNA, SPDYE14, AC211486.3, Y_RNA, SPDYE15, PMS2P2, Y_RNA, STAG3L1, Y_RNA, AC211486.1, TRIM73, NSUN5P1, POM121C, AC211429.1, SPDYE5, PMS2P3, Y_RNA, HIP1, AC004491.1, CCL26.
- chr7:102,433,106–102,473,168, 5 genes, copy number 6 (within-gene range 3–6): ORAI2, ALKBH4, LRWD1, MIR5090, MIR4467.
- chr7:138,404,195–138,589,996, 4 genes, copy number 5: PTMAP10, IMPDH1P3, TRIM24, RPS3AP28.
- chr8:42,896,946–43,085,788, 5 genes, copy number 5 (within-gene range 2–5): HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P.
- chr9:15,422,704–15,544,294, 7 genes, copy number 5: SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P.
- chr9:33,817,160–34,050,244, 8 genes, copy number 5: UBE2R2, Y_RNA, RNU4ATAC11P, UBAP2, SNORD121B, SNORD121A, OSTCP8, RN7SKP114.
- chr9:88,384,902–88,485,325, 5 genes, copy number 5: AL353748.3, SPIN1, AL353748.2, HNRNPA1P14, AL353748.1.
- chr9:125,194,649–125,372,766, 8 genes, copy number 5–6: RPSAP76, RABEPK, HSPA5, AL354710.2, GAPVD1, AL354710.1, RNU6-1020P, AL627223.1.
- chr10:12,068,954–12,328,389, 8 genes, copy number 5–6: DHTKD1, RNU6-88P, SEC61A2, MIR548AK, NUDT5, CDC123, AL512770.1, RN7SL198P.
- chr10:21,492,658–21,526,368, 3 genes, copy number 5: MIR1915HG, MIR1915, SKIDA1.
- chr10:26,973,793–27,259,455, 9 genes, copy number 5 (within-gene range 3–5): ANKRD26, RNU6-490P, YME1L1, MASTL, ACBD5, RNU2-24P, RNU7-12P, AL160291.1, LRRC37A6P.
- chr10:67,849,525–67,874,911, 3 genes, copy number 5: AL133551.1, RNU6-523P, RPL12P8.
- chr11:3,671,083–3,797,792, 3 genes, copy number 5 (within-gene range 2–5): NUP98, RNU6-1143P, RNU7-50P.
- chr11:62,646,848–62,787,342, 19 genes, copy number 6: INTS5, AP001458.2, C11orf98, LBHD1, CSKMT, SNORA57, UQCC3, UBXN1, LRRN4CL, BSCL2, HNRNPUL2-BSCL2, GNG3, HNRNPUL2, TTC9C, ZBTB3, POLR2G, AP001160.2, TAF6L, AP001160.3.
- chr11:118,893,875–118,998,004, 9 genes, copy number 5 (within-gene range 1–5): BCL9L, MIR4492, UPK2, RN7SL688P, Y_RNA, FOXR1, Metazoa_SRP, Y_RNA, CENATAC-DT.
- chr12:55,829,608–55,973,317, 10 genes, copy number 5 (within-gene range 3–5): TMEM198B, MMP19, OLA1P3, GSTP1P1, PYM1, DGKA, AC025162.2, PMEL, CDK2, AC025162.1.
- chr12:123,282,916–123,533,719, 10 genes, copy number 5–6 (within-gene range 2–6): RNA5SP375, SBNO1, Y_RNA, SBNO1-AS1, MIR8072, KMT5A, RILPL2, COPS5P2, SNRNP35, RILPL1.
- chr14:22,147,995–22,511,024, 56 genes, copy number 6–12: TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, TRAV26-2, TRAV34, TRAV35, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31.
- chr15:41,320,794–41,409,403, 3 genes, copy number 5 (within-gene range 4–5): NUSAP1, AC087721.1, NDUFAF1.
- chr15:84,669,538–84,806,445, 4 genes, copy number 5: SEC11A, AC115102.1, ZNF592, AC012291.2.
- chr16:18,983,934–19,067,691, 4 genes, copy number 5 (within-gene range 3–5): TMC7, RNU6-1340P, AC099518.4, AC099518.2.
- chr16:30,075,978–30,123,506, 8 genes, copy number 6: PPP4C, TBX6, YPEL3, AC012645.1, GDPD3, AC012645.2, AC012645.4, MAPK3.
- chr16:30,336,400–30,445,874, 13 genes, copy number 6: AC106782.4, CD2BP2, CD2BP2-DT, TBC1D10B, AC106782.5, MYLPF, ZNF48, SEPTIN1, AC116348.4, ZNF771, SNORA80C, DCTPP1, SEPHS2.
- chr19:10,037,803–11,686,569, 101 genes, copy number 5–6 (broad region; genes not listed).
- chr19:12,552,597–12,887,201, 38 genes, copy number 5–7: AC010422.1, PGK1P2, ZNF490, ZNF791, RPL10P16, AC010422.3, MAN2B1, AC010422.5, WDR83, AC010422.8, WDR83OS, AC010422.7, DHPS, AC010422.2, GNG14, FBXW9, AC018761.4, TNPO2, SNORD41, AC018761.1, TRIR, GET3, BEST2, HOOK2, AC018761.3, MIR5684, JUNB, PRDX2, AC018761.2, THSD8, RNASEH2A, RTBDN, AC020934.1, MAST1, MIR6794, DNASE2, AC020934.2, KLF1.
- chr19:48,900,312–49,015,970, 10 genes, copy number 5: NUCB1, NUCB1-AS1, AC026803.1, DHDH, BAX, AC026803.2, FTL, GYS1, RUVBL2, MIR6798.
- chr20:3,820,524–4,075,165, 11 genes, copy number 5–6 (within-gene range 3–6): AP5S1, MAVS, PANK2-AS1, PANK2, MIR103A2, MIR103B2, AL031670.1, RNF24, FTLP3, RPL21P2, AL356414.1.

Autosomal genes at a single copy (total copy number 1): 7,589. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
